CCDI case PBCGBB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/7668392f-8317-4739-a333-946088a492b4

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pheochromocytoma, NOS: ICD-O-3 morphology code: 8700/3; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 5.6 years (2,037 days).

Biospecimens (3 samples)
- Sample 0DRZII: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRZIU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRZJD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
